Somatic mutation profile of tumor specimen TCGA-06-0152-02A (aliquot TCGA-06-0152-02A-01D-2280-08) from TCGA case TCGA-06-0152, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 68.0 years (24,844 days).
Specimen TCGA-06-0152-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 033b6245-08a0-4316-9597-88a5083f602c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0152-10A (Blood Derived Normal), aliquot TCGA-06-0152-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3c62150-6ee9-4ebd-b86b-9acce8d00999

The open-access MAF lists 66 somatic variants for this specimen: 49 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 16, Frame Shift Del 3, Nonsense Mutation 2, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SRD5A2 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs121434249, CM961358, COSV99252598; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555525857, COSV52661319, COSV52679535, COSV53326529; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADCK1 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 66/206 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs374671690; called by muse, mutect2, varscan2
- ADGRA2 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs201586378, COSV59443784; called by muse, mutect2, varscan2
- AFF3 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1326776735, COSV100419954; called by muse, mutect2, varscan2
- AHNAK | c.17281G>A p.A5761T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV57210293; called by muse, mutect2, varscan2
- CCDC57 | c.234C>A p.F78L | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66436370; called by muse, mutect2, varscan2
- CD8A | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 102/281 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs1427820128, COSV52156884; called by muse, mutect2, varscan2
- DENND2C | c.971A>G p.D324G | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs748106457; called by muse, mutect2, varscan2
- DPEP1 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs148401413; called by muse, mutect2, varscan2
- DTX4 | c.1711G>A p.V571I | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs376862310; called by muse, mutect2, varscan2
- ENO3 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 49/238 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); catalogued as rs773760593, COSV52776709; called by muse, mutect2, varscan2
- F5 | c.1047G>T p.R349S | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.366); catalogued as COSV100889290; called by muse, mutect2, varscan2
- GAS2 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.874); catalogued as rs1221007893; called by muse, mutect2, varscan2
- LAMA1 | c.3301G>A p.A1101T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749492484; called by muse, mutect2, varscan2
- LPA | c.2447C>T p.P816L | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs780710402; called by muse, mutect2, varscan2
- NAA11 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs768903280, COSV54514927; called by muse, mutect2, varscan2
- NINL | c.2257G>A p.A753T | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.178); catalogued as rs377283535, COSV99072021; called by muse, mutect2, varscan2
- OPN5 | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 29/110 reads (26%) | catalogued as COSV55246567, COSV99054546; called by muse, mutect2, varscan2
- OR4A15 | c.40G>T p.G14W | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV59037737, COSV59038238; called by muse, mutect2, varscan2
- PACS1 | c.1060G>A p.V354M | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.641); catalogued as COSV57697095; called by muse, mutect2, varscan2
- PEX11A | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 94/294 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55583164; called by muse, mutect2, varscan2
- PLAGL1 | c.443C>A p.P148H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99394611; called by muse, mutect2, varscan2
- PRMT8 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV54212860; called by muse, mutect2, varscan2
- SEL1L2 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs762935961; called by muse, mutect2, varscan2
- SERPINB5 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs145559318, COSV66975210; called by muse, mutect2, varscan2
- SGSM1 | c.1033G>A p.G345R | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771571853, COSV68512384; called by muse, mutect2, varscan2
- SPECC1L | c.2915C>T p.T972M | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as rs778020153; called by muse, mutect2, varscan2
- ST14 | c.1819C>T p.R607W | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1242315506, COSV53837357; called by muse, mutect2, varscan2
- SUGCT | c.1193C>T p.A398V (on ENST00000335693 / NM_001193313.2; = p.A424V on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/454 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as rs762494535, COSV100001766; called by muse, mutect2, varscan2
- SYNE1 | c.463G>A p.V155M (on ENST00000367255 / NM_182961.4; = p.V162M on NM_033071.3) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs774342833, COSV54933314; called by muse, mutect2, varscan2
- TOR1AIP2 | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.928); catalogued as COSV100857492; called by muse, mutect2, varscan2
- A1CF | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 26/53 reads (49%) | called by muse, mutect2, varscan2
- CHD3 | c.1787G>T p.G596V | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR18 | c.238_244del p.F80Mfs*66 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- GRIN1 | c.2433G>T p.E811D | Missense Mutation (SNP) | VAF 55/85 reads (65%) | SIFT tolerated (0.23); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- LLGL2 | c.505A>G p.I169V | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MIS18BP1 | c.2764T>C p.Y922H | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- MROH2B | c.4236G>T p.E1412D | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.501); called by muse, varscan2
- OR11H6 | c.270G>T p.W90C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- PPP4R1 | c.2011_2012del p.L671Gfs*37 (on ENST00000400556 / NM_001042388.3; = p.L654Gfs*37 on NM_005134.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 107/362 reads (30%) | called by pindel, varscan2
- PRDM2 | c.3886C>A p.P1296T | Missense Mutation (SNP) | VAF 71/206 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRDM5 | c.377G>C p.S126T | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SERPINB10 | c.372T>C p.N124= | Splice Region (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- SLC14A2 | c.2348C>A p.A783E | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SLC23A2 | c.1705G>A p.D569N | Missense Mutation (SNP) | VAF 68/325 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLCO4A1 | c.175del p.L59Sfs*60 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- TNFAIP6 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF862 | c.2404G>T p.V802L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALOX12B | c.381C>T p.P127= | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as rs1350613581, COSV100046498, COSV59872008; called by muse, mutect2, varscan2
- ATG16L1 | c.831T>C p.D277= | Silent (SNP) | VAF 18/90 reads (20%) | called by muse, mutect2, varscan2
- C7orf31 | c.840G>A p.S280= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as rs778627102; called by muse, mutect2, varscan2
- CAVIN3 | c.354G>A p.A118= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs757733540, COSV100392561; called by muse, varscan2
- CES1 | c.702A>G p.P234= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs1351459177; called by muse, mutect2, varscan2
- GCM1 | c.1179C>T p.Y393= | Silent (SNP) | VAF 116/341 reads (34%) | catalogued as rs777186773, COSV52521245; called by muse, mutect2, varscan2
- HNRNPL | c.957G>A p.G319= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99670106; called by muse, varscan2
- IGHG4 | c.843C>T p.D281= | Silent (SNP) | VAF 20/398 reads (5%) | catalogued as rs758157147; called by muse, mutect2
- KIFBP | c.279G>A p.R93= | Silent (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- MUC2 | c.1461G>A p.P487= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as rs368964822; called by muse, mutect2, varscan2
- MYH7 | c.4410G>A p.S1470= | Silent (SNP) | VAF 33/128 reads (26%) | catalogued as rs578166720; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- OPN5 | c.657C>T p.Y219= | Silent (SNP) | VAF 49/130 reads (38%) | catalogued as rs375529102, COSV55245422; called by muse, mutect2, varscan2
- PLCD3 | c.2337G>T p.T779= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV51963313; called by muse, mutect2, varscan2
- SOHLH1 | c.864G>A p.A288= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs764239665, COSV53681104; called by muse, mutect2, varscan2
- TADA3 | c.879C>T p.D293= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as rs745606972; called by muse, mutect2, varscan2
- TRPM1 | c.4044C>T p.N1348= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as rs541023956, COSV56642243; called by muse, mutect2, varscan2
- BDNF | c.-21-15591G>A | Intron (SNP) | VAF 8/30 reads (27%) | catalogued as rs756774056; called by muse, mutect2, varscan2
